Somatic mutation profile of tumor specimen TCGA-CH-5753-01A (aliquot TCGA-CH-5753-01A-11D-1576-08) from TCGA case TCGA-CH-5753, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.6 years (25,780 days).
Specimen TCGA-CH-5753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de600035-2a96-4bd6-9b89-2423e5ab4ee3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5753-10A (Blood Derived Normal), aliquot TCGA-CH-5753-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d881a746-d475-4290-92de-a4f80ba2a786

The open-access MAF lists 46 somatic variants for this specimen: 40 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 4, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STRC | c.4012C>T p.R1338* | Nonsense Mutation (SNP) | VAF 49/109 reads (45%) | catalogued as rs755471554, COSV68461389; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs200272726, COSV60914353; called by muse, mutect2, varscan2
- ACAN | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61361593; called by muse, mutect2
- AGL | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV54053268; called by muse, mutect2, varscan2
- CEP152 | c.3746G>A p.G1249E (on ENST00000380950 / NM_001194998.2; = p.G1193E on NM_014985.4) | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs1340553591, COSV57859944; called by muse, mutect2, varscan2
- CFAP251 | c.2017G>C p.V673L | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV56610883; called by muse, mutect2, varscan2
- CNTNAP5 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200941353, COSV70472466; called by muse, mutect2, varscan2
- CSMD3 | c.9663G>A p.W3221* (on ENST00000297405 / NM_001363185.1; = p.W3052* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 114/444 reads (26%) | catalogued as COSV52194301; called by muse, varscan2
- DOCK3 | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56524535; called by muse, mutect2, varscan2
- ELOB | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as rs1209586833, COSV51940829; called by muse, mutect2, varscan2
- F11 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV53007014; called by muse, mutect2, varscan2
- FAM135A | c.1051T>G p.F351V (on ENST00000370479 / NM_001351599.1; = p.F334V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52052292; called by muse, mutect2, varscan2
- FAM163A | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59203818; called by muse, mutect2, varscan2
- GABRE | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV64819847; called by muse, mutect2
- HSPG2 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV65972213; called by muse, mutect2, varscan2
- KCNA4 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.414); catalogued as rs1352740443, COSV60252680, COSV60255848; called by muse, mutect2, varscan2
- LMAN1 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV51827078; called by muse, mutect2, varscan2
- LRP1B | c.5909C>A p.T1970K | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV67226491; called by muse, mutect2
- MCM4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV50624067; called by muse, mutect2, varscan2
- MICAL2 | c.3208G>A p.A1070T | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56320852; called by muse, mutect2, varscan2
- MLEC | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57329719; called by muse, mutect2, varscan2
- MTCL1 | c.4516C>A p.Q1506K (on ENST00000306329 / NM_001378206.1; = p.Q1187K on NM_015210.4) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs865805673, COSV60406635; called by muse, mutect2, varscan2
- MTREX | c.35T>A p.V12E | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV52418658; called by muse, mutect2, varscan2
- NR2F1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.936); catalogued as COSV59068227; called by muse, mutect2, varscan2
- NYNRIN | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV101230697, COSV66842833; called by muse, mutect2, varscan2
- OR4C16 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 146/358 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374191202, COSV58941555; called by muse, mutect2, varscan2
- OR52A1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs199986389; called by muse, mutect2
- PIWIL2 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138817329; called by muse, mutect2, varscan2
- TDRKH | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 117/479 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV64316354, COSV64316820; called by muse, mutect2, varscan2
- TECPR1 | c.3043G>A p.V1015M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775705773, COSV65783655; called by muse, mutect2, varscan2
- TGM7 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV71772848; called by muse, mutect2, varscan2
- TLK2 | c.1188-1G>A p.X396_splice (on ENST00000326270 / NM_001284333.2; = p.X374_splice on NM_006852.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/323 reads (4%) | catalogued as COSV58300666; called by muse, mutect2
- TTLL11 | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV58647059; called by muse, mutect2
- VPS13C | c.2519C>T p.A840V (on ENST00000644861 / NM_020821.3; = p.A797V on NM_017684.5) | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51198038, COSV99830304; called by muse, mutect2, varscan2
- ZNF800 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs768868005, COSV56176079; called by muse, mutect2, varscan2
- IGF2BP1 | c.1275del p.Q426Sfs*61 | Frame Shift Del (DEL) | VAF 51/195 reads (26%) | called by mutect2, pindel, varscan2
- NPEPPS | c.442T>G p.F148V | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDIK1L | c.894dup p.S299Ifs*11 | Frame Shift Ins (INS) | VAF 70/169 reads (41%) | called by mutect2, varscan2
- SRFBP1 | c.659del p.K220Rfs*8 | Frame Shift Del (DEL) | VAF 58/163 reads (36%) | called by mutect2, pindel, varscan2
- TTN | c.37585del p.M12529Cfs*3 (on ENST00000591111; = p.M5105Cfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 221/656 reads (34%) | called by mutect2, pindel, varscan2
- FDFT1 | c.270G>A p.V90= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV55042543; called by muse, mutect2
- RYR3 | c.720C>T p.D240= | Silent (SNP) | VAF 50/336 reads (15%) | catalogued as COSV66791799; called by muse, mutect2, varscan2
- SPATA25 | c.498C>T p.T166= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as rs764903249, COSV51942393; called by muse, mutect2, varscan2
- TMEM130 | c.300C>T p.P100= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as rs782349114, COSV59559384; called by muse, mutect2
- GAD1 | c.1120-494A>T | Intron (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- ZNF99 | c.*255C>A | 3'UTR (SNP) | VAF 101/244 reads (41%) | catalogued as COSV101233987, COSV68055304, COSV68055875; called by muse, mutect2, varscan2
